Somatic mutation profile of tumor specimen TARGET-30-PATYMS-01A (aliquot TARGET-30-PATYMS-01A-01D) from TARGET case TARGET-30-PATYMS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,596 days).
Specimen TARGET-30-PATYMS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b204fbce-134b-4bc0-884f-8bcee0a44b78.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATYMS-10A (Blood Derived Normal), aliquot TARGET-30-PATYMS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02fce93b-95ea-47c8-9240-0225c166a16f

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LLGL1 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57501821; called by muse, mutect2, varscan2
- HELB | c.2869_2885del p.S958Rfs*34 | Frame Shift Del (DEL) | VAF 56/167 reads (34%) | called by mutect2, pindel, varscan2
